Somatic mutation profile of tumor specimen TCGA-KK-A7B3-01A (aliquot TCGA-KK-A7B3-01A-11D-A33T-08) from TCGA case TCGA-KK-A7B3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.5 years (22,830 days).
Specimen TCGA-KK-A7B3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 807cd88e-682d-407a-993d-8354a93ea661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7B3-11A (Solid Tissue Normal), aliquot TCGA-KK-A7B3-11A-21D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71677428-8d53-49c7-8317-4085317427e2

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); catalogued as COSV99443730; called by muse, mutect2, varscan2
- BRWD1 | c.3352C>T p.P1118S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768371827, COSV100313685; called by muse, mutect2, varscan2
- CAMKV | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377281206; called by muse, mutect2, varscan2
- CHAMP1 | c.198A>T p.K66N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100778830; called by muse, mutect2, varscan2
- DKK1 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100906555; called by muse, mutect2, varscan2
- GALNT14 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs148056182; called by muse, mutect2, varscan2
- GCK | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1421126047, COSV99790042; called by muse, mutect2, varscan2
- HMCN1 | c.3421C>T p.R1141C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757779094, COSV99631693; called by muse, mutect2, varscan2
- HS6ST1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV52131627; called by mutect2, varscan2
- KIAA1614 | c.1829C>G p.S610C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV62551073; called by muse, mutect2, varscan2
- KIAA1614 | c.2445A>C p.K815N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100851228; called by muse, mutect2, varscan2
- MBNL3 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV100898496; called by muse, mutect2, varscan2
- MPO | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99229054; called by muse, mutect2, varscan2
- MUSK | c.57C>A p.S19R | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99504590; called by muse, mutect2, varscan2
- OR8K5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | catalogued as rs147577134, COSV57889485; called by muse, mutect2, varscan2
- PDZD9 | c.432T>A p.D144E (on ENST00000424898 / NM_001363519.1; = p.D84E on NM_173806.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99193358; called by muse, mutect2, varscan2
- PIKFYVE | c.2480T>G p.F827C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1321179300, COSV100011050; called by muse, mutect2, varscan2
- PRH1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs372677799; called by mutect2, varscan2
- QRICH1 | c.2105C>G p.P702R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100455092, COSV58707537; called by muse, mutect2, varscan2
- SLIT3 | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100268630; called by muse, mutect2, varscan2
- SULT1C3 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.425); catalogued as COSV100227524; called by muse, mutect2, varscan2
- TCEAL6 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV101035909, COSV65653934; called by muse, mutect2, varscan2
- TMEM132E | c.1560C>G p.D520E (on ENST00000321639; = p.D610E on NM_001304438.2) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100396533; called by muse, mutect2, varscan2
- TP53BP1 | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV55500458; called by muse, mutect2, varscan2
- TP53BP2 | c.2900C>T p.T967M (on ENST00000343537 / NM_001031685.3; = p.T838M on NM_005426.2) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100636699; called by muse, mutect2, varscan2
- UGT3A1 | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.232); catalogued as COSV99954986; called by muse, mutect2, varscan2
- MBD1 | c.101_102del p.Y34Lfs*14 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- NTRK1 | c.2188_2193del p.Q730_L731del | In Frame Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- RBM45 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DCAF1 | c.1302C>G p.P434= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- DEF8 | c.789G>C p.L263= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as COSV99240624; called by muse, mutect2, varscan2
- DHTKD1 | c.2103C>T p.Y701= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs766801757, COSV53808945; ClinVar: likely benign; called by muse, mutect2, varscan2
- HYDIN | c.1317C>T p.C439= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs544937612, COSV55504538; called by mutect2, varscan2
- KL | c.1956C>A p.A652= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV101199130; called by muse, mutect2, varscan2
- SYNE2 | c.18633G>A p.T6211= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs755914136, COSV59945638; ClinVar: likely benign; called by muse, mutect2, varscan2
